Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A57M, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A57M-01A (Primary Tumor).

Gross Description: A mass is located in left heel skin and ulcerated, with 4x4x1.0cm, firm, brown, black-gray surface

Microscopic Description: Epidermis is necrotic ulcerated and hyperplastic. Tumor is composed of spindle or oval tumor cells with quite abundant cytoplasm. Sometime the cytoplasm contains finely divided melanin pigment granulae. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are present. Tumor cells invade into dermis or fat tissue.

Diagnosis Details: Malignant melanoma

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, foot non-glabrous, per TSS.

Tumor size: 4 x 4 x 1 cm

Tumor features: Ulcerated, Pigmented, Necrotic

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 1/2 positive for metastasis (Left inguinal lymph node 1/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow tumor thickness at diagnosis = 8 mm

ICD-O-3

malignant melanoma, NOS
8720/3

Site: Skin @ Heel
C44.7
12/20/12
AS

Source: NCI Genomic Data Commons file 00b65aca-b61c-41f6-b97f-93473f79d270 (TCGA-EB-A57M.CE05E5B1-1D6C-4B7E-A32E-846E80477075.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).